Gene-level copy-number profile of tumor specimen TCGA-36-1576-01A from TCGA case TCGA-36-1576, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.1 years (27,778 days).
Specimen TCGA-36-1576-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.18f46108-26bb-42a2-802f-2205ae194d39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1576-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ff73b637-d6a9-425e-b38d-43c7260e7642

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 35; copy number 2: 2,791; copy number 3: 5,636; copy number 4: 20,651; copy number 5: 8,371; copy number 6: 10,154; copy number 7: 5,580; copy number 8: 1,293; copy number 9: 4,248; copy number 10: 221; copy number 11: 183; copy number 12: 17; copy number 13: 19; copy number 14: 104; copy number 15: 32; copy number 16: 82; copy number 17: 35; copy number 18: 17; copy number 19: 48; copy number 20: 171; copy number 25: 26; copy number 26: 45; copy number 28: 1; copy number 30: 41; copy number 41: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1576-01): tumor purity 0.4, ploidy 4.21, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,300 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–119,896,515, 38 genes, copy number 10–16: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30.
- chr2:104,656,135–105,249,794, 19 genes, copy number 9: AC068057.3, AC013402.1, RPL23AP27, AC068057.1, AC068057.2, SNORA72, LINC01114, HMGB3P11, PANTR1, AC018730.1, POU3F3, LINC01159, AC010884.1, MRPS9-AS2, MRPS9, MRPS9-AS1, LINC01918, GPR45, AC012360.2.
- chr2:106,304,755–107,407,329, 19 genes, copy number 9 (within-gene range 5–9): RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1.
- chr3:90,202,316–99,018,562, 81 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr3:106,160,417–198,222,513, 1,656 genes, copy number 9–11 (broad region; genes not listed).
- chr4:136,795,919–137,212,799, 1 gene, copy number 28 (within-gene range 6–28): LINC02511.
- chr4:137,807,706–140,154,184, 45 genes, copy number 9–14: AC131956.1, AC097511.1, LINC00616, SLC7A11-AS1, SLC7A11, AC093903.1, LINC00498, LINC00499, LINC00500, AC105416.1, AC098859.1, AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16, MAML3, AC108053.1, RN7SKP253, AC131182.1.
- chr4:142,933,195–143,557,486, 14 genes, copy number 18: AC104596.1, AC104596.2, USP38, AC097658.2, Y_RNA, GAB1, MIR3139, AC097658.1, AC097658.3, RPSAP36, AC104685.1, SMARCA5-AS1, SMARCA5, AC139713.1.
- chr4:143,559,472–143,762,093, 3 genes, copy number 18: GUSBP5, FREM3, AC104090.1.
- chr8:38,105,493–38,144,076, 1 gene, copy number 17 (within-gene range 6–17): ASH2L.
- chr8:38,123,274–39,580,134, 39 genes, copy number 17–30 (within-gene range 6–30): AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1.
- chr8:41,803,349–42,371,808, 15 genes, copy number 14: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9 (broad region; genes not listed).
- chr14:18,333,726–21,537,216, 190 genes, copy number 13–20 (broad region; genes not listed).
- chr14:72,515,407–75,663,214, 117 genes, copy number 10–14 (broad region; genes not listed).
- chr14:75,649,791–75,660,876, 1 gene, copy number 14: ERG28.
- chr14:81,169,776–82,030,349, 17 genes, copy number 12: AL136040.2, GTF2A1, SNORA79, AL136040.1, DYNLL1P1, UNGP3, STON2, AL121769.1, DYNLL1P2, LINC02308, SEL1L, LINC01467, EEF1A1P2, LINC02311, AL355838.1, RPL9P6, EIF3LP1.
- chr14:82,642,605–83,048,640, 6 genes, copy number 15: LINC02301, ENSAP2, AL355095.1, AL359238.1, AL162872.1, RNU7-51P.
- chr14:88,024,519–91,780,707, 77 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:20,999,596–21,043,760, 1 gene, copy number 15 (within-gene range 4–15): USP22.
- chr17:21,075,362–21,594,180, 21 genes, copy number 15: LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2.
- chr18:30,290,161–32,773,023, 56 genes, copy number 11–19 (within-gene range 4–19): AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14.
- chr19:28,316,705–30,085,893, 46 genes, copy number 14–41 (within-gene range 8–41): AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:42,068,477–45,038,198, 149 genes, copy number 11–16 (within-gene range 3–16) (broad region; genes not listed).
- chr19:45,883,608–46,601,200, 36 genes, copy number 30 (within-gene range 4–30): IRF2BP1, MYPOP, NANOS2, NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2, IGFL2-AS1, IGFL1P1, AC006262.1, RPL12P41, AC006262.3, IGFL1, AC006262.4, IGFL1P2, HIF3A, RNU6-924P, AC007193.2, PPP5C, AC007193.1, AC007193.3, CCDC8, PNMA8C, PNMA8A, PPP5D1, PNMA8B, AC011484.1, AC011551.1.
- chr19:54,069,895–54,473,296, 45 genes, copy number 26: TARM1, OSCAR, NDUFA3, TFPT, PRPF31, AC245052.4, CNOT3, LENG1, TMC4, MBOAT7, TSEN34, AC245052.1, RPS9, AC245052.2, LILRB3, AC245052.7, AC245052.3, LILRA6, AC245052.6, LILRB5, RNU6-1307P, AC245052.5, LILRB2, MIR4752, AC245884.5, AC245884.12, AC245884.7, AC245884.2, LILRA5, AC245884.11, VN1R104P, AC245884.6, LILRA4, LAIR1, AC245884.4, TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8, LENG8-AS1, AC245884.3, LENG8, LENG9, CDC42EP5.
- chr20:2,536,607–5,611,006, 100 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr20:24,297,585–64,313,132, 973 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
